Somatic mutation profile of tumor specimen BA2883D (aliquot aq-BA2883D) from BEATAML1.0 case 2395, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated CEBPA; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.3 years (26,054 days).
Specimen BA2883D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d5d05aa-85fe-408e-8bd1-4b0931f54f21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2943D (Solid Tissue Normal), aliquot aq-BA2943D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86456635-d8af-46b1-85b5-e1051183c3b7

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 2, Intron 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 58/116 reads (50%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MYO16 | c.275C>T p.S92L | Missense Mutation (SNP) | VAF 43/72 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51786860; called by muse, mutect2, varscan2
- SPG11 | c.1775C>T p.S592L | Missense Mutation (SNP) | VAF 103/233 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.487); catalogued as rs373796566; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TET2 | c.4096C>A p.R1366S | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104371869; called by muse, mutect2, varscan2
- BMP3 | c.1141G>T p.D381Y | Missense Mutation (SNP) | VAF 64/130 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- CNTNAP1 | c.1667A>G p.Y556C | Missense Mutation (SNP) | VAF 52/99 reads (53%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.525); called by muse, varscan2
- COL6A6 | c.2374G>C p.V792L | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT tolerated (0.32); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- EZH2 | c.1396-3C>G | Splice Region (SNP) | VAF 34/42 reads (81%) | called by muse, mutect2, varscan2
- RBMS1 | c.742G>A p.G248R | Missense Mutation (SNP) | VAF 57/111 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, varscan2
- RUNX1 | c.1138_1141dup p.G381Vfs*193 (on ENST00000344691 / NM_001001890.3; = p.G408Vfs*193 on NM_001754.5) | Frame Shift Ins (INS) | VAF 12/56 reads (21%) | called by mutect2, pindel, varscan2
- DENND4B | c.591G>T p.L197= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as rs1196508356; called by muse, mutect2
- PILRA | c.309G>A p.E103= | Silent (SNP) | VAF 102/223 reads (46%) | catalogued as COSV52200164; called by muse, varscan2
- DST | c.4297-2776G>T | Intron (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
